Surgical pathology report (de-identified scan), TCGA case TCGA-23-1031, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1031-01A (Primary Tumor).

[page 1 of 5]
DIAGNOSIS:

- 1: OMENTUM, PARTIAL OMENTECTOMY:
-Metastatic serous carcinoma (see comment)
- 2: FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:
-Serous adenocarcinoma, grade 3
-Tumor subtotally replaces ovary
-There is also extensive serosal surface ovarian involvement by carcinoma
-Carcinoma also involves paraovarian and paratubal soft tissues
-Serosal surface of fallopian tube is involved by carcinoma
-Free-floating aggregates of carcinoma cells are present within the lumen of the fallopian tube
-Other findings include:
-Paratubal cystic Walthard rest
-Tiny benign paraovarian adenofibroma
-Atrophic changes and cystic epithelial inclusions of ovary
- 3: FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:
-Serous adenocarcinoma, grade 3 (see comment)
-Ovary is nearly totally replaced by invasive carcinoma
-There is also extensive serosal surface involvement of the ovary by tumor
-Tumor is present in paraovarian and paratubal adnexal soft tissues
-Nodular aggregates of carcinoma are adherent to the fimbriated end of fallopian tube
-Tiny free-floating aggregates of carcinoma are present within lumen of fallopian tube
-Mild acute and chronic inflammation of serosa/subserosa of fallopian tube
-Lymphovascular ectasia and stromal edema of fallopian tube
- 4: LARGE INTESTINE, RECTOSIGMOID TUMOR, EXCISION:
-Metastatic serous carcinoma (see comment)

(continued on next page)□

- 5: LARGE INTESTINE, CECAL TUMOR, EXCISION:
-Metastatic serous carcinoma (see comment)
- 6: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
-Metastatic serous carcinoma involving:
-Serosal surface, subserosa, and external muscular wall (myometrium) of uterus
-Parametrial soft tissues

[page 2 of 5]
- Cervix and vaginal cuff are free of tumor
- Inactive (atrophic to focally weakly proliferative) endometrium, some cystically dilated glands, foci of ciliated epithelial metaplasia, and reactive stromal lymphoid aggregates
- Microscopic (less than 1.5 mm in diameter) epithelioid leiomyoma, plexiform type (plexiform tumorlet) apparently arising from smooth muscle in the wall of an intrauterine vein (slides 0 and 0 ds-1)
- Microscopic cellular leiomyoma (about 1 mm in diameter) and small cellular uterine leiomyoma (about 5 mm in diameter)
- Two small uterine leiomyomas, larger is partially hyalinized
- Adenomyosis
- Uterine serosal adhesions
- Chronic and mild acute cervicitis with reserve cell hyperplasia, squamous metaplasia, reactive epithelial changes, and endocervical nabothian cysts
- Small benign endocervical polyp
- Vaginal cuff mucosa with chronic and mild acute inflammation
- 7: MESENTERY OF SMALL INTESTINE, BIOPSY:
- Metastatic serous carcinoma involving fragments of lymph nodes and mesenteric fat/fibroadipose tissue (see comment)
- 8: [SOFT TISSUE], RIGHT ADNEKAL, EXCISION:
- Serous adenocarcinoma (see comment)
- 9: LIVER, BIOPSY:
- Metastatic serous carcinoma involving capsular surface and invading liver parenchyma (see comment)
- Liver also shows macrovesicular steatosis, mild pleomorphism of hepatocytes, chronic inflammation in portal triads and adjacent to tumor and focal portal fibrosis
- 10: SOFT TISSUE, CUL DE SAC, TUMOR, EXCISION:
- Metastatic serous carcinoma (see comment)

COMMENT: The right ovary is massively involved and is nearly totally replaced by adenocarcinoma. Tumor in the right ovary appears to be primary at that site. The left ovarian neoplasm probably represents a second (synchronous) primary neoplasm. Carcinoma in all of the involved sites exhibits predominantly serous features, albeit with focal 'undifferentiated'/anaplastic components and pseudo-transitional appearance in some areas. In a few of the involved sites, the tumor exhibits hobnail and/or clear cell features. The carcinoma exhibits papillary, glandular and solid patterns of growth. Tumor-associated psammoma bodies are prominent in most of the involved sites. Tumor necrosis, secondary acute and chronic inflammatory changes, fibrosing stromal reaction to tumor, and adhesions are noted in many of the involved sites. Lymphovascular invasion by carcinoma is present virtually in most of the involved

(continued on next page)□

sites. Preliminary pathologic findings were reported to the office of

HISTORY: Ovarian papillary carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM WITH FROZEN SECTION NO. 1

Labeled 'omentum with frozen section #1' and received fresh in the Operating Room for intraoperative frozen section is a 20 x 11.5 x 1.5 cm indurated portion of tan-yellow omental fat that is subtotally replaced by nodular and plaque-like aggregates of firm white metastatic tumor. A representative fresh sterile portion of the

[page 3 of 5]
tumor is placed in _____ and submitted to for clonogenic assays. Another representative portion of tumor is frozen and sectioned for intraoperative diagnosis. Interpretation of the frozen section was rendered by Dr. _____. The remaining frozen tissue and the rest of the specimen are subsequently fixed in formalin.

Representative sections.

- A. Remnant of frozen section #1 - 1
- B. Unfrozen omental tumor - 1

2: LEFT TUBE AND OVARY

Labeled "left tube and ovary" and received in formalin is a salpingo-oophorectomy specimen. The ovary is 3.6 x 1.8 x 1.6 cm. The serosal surface of the ovary shows extensive involvement by papillated and nodular tan tumor. Cut sections of the ovary reveal nearly total replacement by firm, white-yellow invasive tumor. Nodular and plaque-like aggregates of tumor are also present in the paraovarian and paratubal soft tissues. The fallopian tube has fimbria at one end, is about 2.8 cm long and up to 0.6 cm in diameter. There is a plaque-like aggregate of firm, yellow-tan tumor focally involving the serosal surface of the fallopian tube. The latter measures about 0.5 cm in diameter. Cross sections of the fallopian tube reveal a pinpoint patent lumen, about 0.1 cm in diameter, and no invasive tumor in the muscular wall of the fallopian tube.

Representative sections.

- C. Fallopian tube and paratubal tumor - 2
- D,E. Ovarian tumor - 1 each
- F. Ovary and adnexal soft tissues with tumor - 1

3: RIGHT TUBE AND OVARY

Labeled "right tube and ovary" and received in formalin is a salpingo-oophorectomy specimen. The ovary is massively enlarged, about 8.6 x 7.4 x 6.2 cm. The ovary is focally ruptured and partially fragmented. The serosal surface of the ovary shows extensive involvement by papillated and nodular plaque-like aggregates of semi-firm to firm tan-white tumor. Cut sections of the ovary reveal nearly total replacement by mostly firm, yellow-tan tumor with areas of cystic degeneration, focal hemorrhages, and necrosis noted. No residual non-neoplastic ovarian tissue is grossly evident. The fallopian tube has fimbria at one end, is 4.1 cm long and up to 0.7 cm in diameter. Attached to the fimbriated end of the fallopian tube, there are several firm, yellow-tan tumor nodules, the

(continued on next page)□

largest of which measures about 1.2 cm in diameter. The serosal surface of the fallopian tube is pink-tan and relatively smooth elsewhere. Cross sections of the fallopian tube reveal a stellate patent lumen, up to about 0.2 cm in diameter and an edematous wall. No invasive tumor is seen in the fallopian tube.

Representative sections.

- G. Fallopian tube and tumor nodule attached to fimbriated end - 2
- H-L. Ovarian tumor - 1 each

4: SIGMOID RECTAL TUMOR

Labeled "sigmoid rectal tumor" and received in formalin is a 2.6 x 1.4 x 1.2 cm aggregate of firm, focally hemorrhagic red-brown to white tumor fragments, some of which are semi-soft and friable and others of which are firm.

Representative section.

- M. Tumor - 1

5: CECAL TUMOR

Labeled "cecal tumor" and received in formalin is a 1.5 x 1.0 x 0.6 cm aggregate of semi-soft, friable and firmer tan tumor.

Representative section.

[page 4 of 5]
N. Tumor - 1

6: UTERUS AND CERVIX

Labeled "uterus and cervix" and received in formalin is a 70 gram total hysterectomy specimen. The uterus is symmetric. The uterus measures about 7.7 cm from the fundus to the ectocervix, 3.6 cm from cornu to cornu, and a maximum of 3.4 cm from the anterior surface to the posterior surface. The uterine serosa is red-tan and shaggy showing adhesions and nodular and plaque-like aggregates of semi-firm tan tumor anteriorly and posteriorly. Nodular aggregates of firm tan metastatic tumor are also present in the parametrial soft tissues. The cervix is about 3.1 cm long and up to 2.2 cm in diameter. The ectocervical mucosa is pale tan and smooth. The external cervical os is slit-shaped, 1.1 cm in diameter, and patent. The uterus is incised on both sides. The cervical transformation zone is distinct. The endocervical canal is about 2.4 cm long and lined by tan, focally rugose mucosa. Cut sections of the cervix reveal several mucus-filled cysts, ranging from less than 0.1 to 0.3 cm in diameter. The endometrial cavity is about 4 cm long and up to 1.2 cm in width. The endometrium is tan, smooth, and about 0.1 cm in maximum thickness. No primary gross pathologic lesions of the endometrium are seen. The muscular uterine wall has a maximum thickness of about 1.7 cm. Within the uterus, there are three sharply circumscribed intramural leiomyomas, about 0.5, 0.6 and 1.7 cm in diameter. The smallest and second smallest have firm solid tan whorled cut surfaces. The larger leiomyoma has a tan-white whorled cut surface with areas of hyalinization. No areas of necrosis or hemorrhages are seen in either leiomyoma. The outermost aspect of the muscular uterine wall is focally involved by tumor in the anterior and posterior uterine corpus.

Representative sections.

O. Anterior uterine corpus with smaller leiomyoma - 1

P. Anterior cervix - 1

Q. Posterior uterine corpus - 1

R. Posterior cervix - 1

S. Larger leiomyoma - 1

T. Serosa and parametria with adhesions and tumor nodules - Multiple

(continued on next page)□

7: SMALL BOWEL MESENTERY

Labeled "small bowel mesentery" and received in formalin is a 2.5 x 1.2 x 0.6 cm aggregate of yellow fatty tissue within which there are multiple irregular firm nodular aggregates of white-tan tumor, the largest of which measures about 0.5 cm in diameter.

Representative sections.

U. Tumor - Multiple

8: RIGHT ADNEXA

Labeled "right adnexa" and received in formalin is a 1.2 x 0.8 x 0.5 cm firm nodular portion of tan-white tumor.

Representative section.

V. Tumor - 1

9: LIVER BIOPSY

Labeled "liver biopsy" and received in formalin is a 2.0 x 1.5 x 0.5 cm aggregate of tan-brown liver tissue which shows extensive cautery artifacts and nodular to irregular aggregates of firm, tan-white tumor.

Representative sections.

W. Liver with tumor - 2

10: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is a 5.0 x 3.5 x 2.0 cm aggregate of multiple fragments of semi-soft friable and

[page 5 of 5]
firmer tan-white tumor.
Representative section.
X. Tumor - 1

Gross dictated by

OPERATIVE CONSULT (FROZEN):

1. Omentum:
- Metastatic adenocarcinoma with some papillations and calcifications, favor mullerian origin
- Tumor taken for clonogenic assay

Special Studies: Frozen Section ; H&E-stained step sections

See Also: None

I, the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file 54593566-4772-47fa-b515-5f2f09b62ce3 (TCGA-23-1031.6D440E0F-B290-48CB-8445-C268B444ADE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).